CPTAC case C3L-02707 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/533e8ab7-099b-458d-bd82-ccaa066b5f82

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1959; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Temporal lobe; Age at diagnosis: 58.2 years (21,250 days); Year of diagnosis: 2017; Last known disease status: With tumor; Days to last known disease status: 91 days; Days to last follow up: 91 days.
   Pathology details: Greatest tumor dimension: 2 cm.

Follow-up (1 entry)
- Days to follow up: 91 days; Disease response: With Tumor; Karnofsky performance status: 60.

Other clinical attributes
- Weight: 68.04 kg; Height: 177.8 cm; BMI: 21.52.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02707-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 1 day; Method of sample procurement: Blood Draw.
- Sample C3L-02707-71: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 77 mg; Time between excision and freezing: 12 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02707-21: Section location: Temporal Lobe; Percent tumor nuclei: 85; Percent necrosis: 5.
- Sample C3L-02707-72: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 75 mg; Time between excision and freezing: 12 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02707-22: Section location: Temporal Lobe; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3L-02707-75: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 59 mg; Time between excision and freezing: 12 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02707-25: Section location: Temporal Lobe; Percent tumor nuclei: 85; Percent necrosis: 5.
